Somatic mutation profile of tumor specimen TARGET-10-PAPESZ-09A (aliquot TARGET-10-PAPESZ-09A-01D) from TARGET case TARGET-10-PAPESZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,418 days).
Specimen TARGET-10-PAPESZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0169e893-a469-41fd-b85d-52557b3e1146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPESZ-14A (Bone Marrow Normal), aliquot TARGET-10-PAPESZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9640823-6949-41d4-9982-644c027c7575

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ENTPD3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs780128361; called by mutect2, varscan2
- GRIA1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53602401; called by muse, mutect2, varscan2
- ARHGEF12 | c.9dup p.T4Hfs*29 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- ARHGEF12 | c.10delinsCC p.T4Pfs*29 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2*, pindel, varscan2*
- DNTTIP2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.097); called by muse, mutect2
- GPR83 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LRBA | c.6096C>G p.I2032M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); called by muse, mutect2
- TRMT10A | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- VWDE | c.1505C>G p.S502* | Nonsense Mutation (SNP) | VAF 37/117 reads (32%) | called by muse, mutect2, varscan2
- ACSL1 | c.1137A>T p.G379= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- EXOC2 | c.696A>G p.E232= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV57871422; called by muse, mutect2
- HPSE2 | c.1146G>C p.V382= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- RUSC2 | c.1641G>T p.L547= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- ATP8B1 | c.1631-27C>G | Intron (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- PSTPIP1 | c.839-15G>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs1263276335; called by muse, mutect2, varscan2
- RTTN | c.5951-55C>T | Intron (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- SNORD116-21 | n.14C>T | RNA (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
